CCDI case PBBPRN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/46661fa5-dd99-4344-bb63-e700c4e0af85

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pigmented dermatofibrosarcoma protuberans: ICD-O-3 morphology code: 8833/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 15.1 years (5,514 days).

Biospecimens (3 samples)
- Sample 0DEHN5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEHPE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEHPF: Tissue type: Tumor; Specimen type: Solid Tissue.
